Gene-level copy-number profile of specimen HCM-CSHL-0368-D37-85P from HCMI case HCM-CSHL-0368-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Noninfiltrating intraductal papillary adenocarcinoma; Tissue or organ of origin: Gallbladder; AJCC pathologic stage: Stage 0; Tumor grade: GB; Age at diagnosis: 65.9 years (24,078 days).
Specimen HCM-CSHL-0368-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4dc05455-3b24-4984-be1b-71f53e13d2b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0368-D37-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/1ec26d47-dece-42a3-bd0c-1b93352a4b56

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,612; copy number 2: 46,645; copy number 3: 8,607; copy number 4: 41; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:11,797,468–11,828,845, 2 genes, copy number 6: AC010654.1, BCAR4.

Autosomal genes at a single copy (total copy number 1): 756. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
